Somatic mutation profile of tumor specimen C3N-03484-02 (aliquot CPT0285140006) from CPTAC case C3N-03484, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,570 days).
Specimen C3N-03484-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aac636a2-9cb2-4462-81fc-570d2c8d39b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03484-31 (Blood Derived Normal), aliquot CPT0285150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ea0ee8-c340-4522-bfbc-9a53fab6ef4e

The open-access MAF lists 124 somatic variants for this specimen: 77 protein-altering or splice-affecting, 32 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 32, Nonsense Mutation 9, Intron 6, 5'Flank 3, Frame Shift Del 2, 3'UTR 2, Splice Region 2, RNA 2, 3'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAH | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 103/622 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62644503, CM112731, CM941134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETX | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 166/344 reads (48%) | catalogued as rs121434376, CM040516, COSV99810992; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOD1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755737247, COSV66291675; called by muse, mutect2, varscan2
- ADGRF5 | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs751080249, COSV99345245; called by muse, mutect2, varscan2
- ALAS2 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376961603; called by muse, mutect2, varscan2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- CABP5 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138142491; called by muse, mutect2, varscan2
- CAPN6 | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs756900127; called by muse, mutect2, varscan2
- CAVIN2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571084497; called by muse, mutect2, varscan2
- CCDC117 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99968954; called by muse, mutect2, varscan2
- CR2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 185/423 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs777733651; called by muse, mutect2, varscan2
- CTU1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 154/517 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1417293226, COSV101361805; called by muse, mutect2, varscan2
- CUEDC1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1385077512, COSV100804714; called by muse, mutect2, varscan2
- CYP27B1 | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 329/840 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749745310, COSV56986907; called by muse, mutect2, varscan2
- CYP4B1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.358); catalogued as rs954937628; called by muse, mutect2, varscan2
- GIMAP5 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 90/335 reads (27%) | catalogued as rs780355836; called by muse, mutect2, varscan2
- GON4L | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 162/397 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547557420, COSV99675728; called by muse, mutect2, varscan2
- H2BC1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 103/268 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); catalogued as rs1324318612, COSV99219330; called by muse, mutect2, varscan2
- HDAC8 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs782048506; called by muse, mutect2
- HSD17B11 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs148948833; called by muse, mutect2, varscan2
- IGHV1-2 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs1061871; called by muse, mutect2, varscan2
- ITGAV | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53721184; called by muse, mutect2, varscan2
- KCNV1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192812890; called by muse, mutect2, varscan2
- KHDRBS3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764983380, COSV63417522; called by muse, mutect2, varscan2
- KLHL6 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761606107, COSV58067102; called by muse, mutect2, varscan2
- KRT73 | c.726C>T p.D242= | Splice Region (SNP) | VAF 85/214 reads (40%) | catalogued as rs115179423, COSV59841882; called by muse, mutect2, varscan2
- LRRC7 | c.157C>T p.R53* (on ENST00000651989 / NM_001370785.2; = p.R20* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 132/317 reads (42%) | catalogued as COSV50563614; called by muse, mutect2, varscan2
- MIDEAS | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776105694; called by muse, mutect2, varscan2
- NRIP1 | c.2179A>G p.K727E | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs749747897; called by muse, mutect2, varscan2
- OR5B2 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV56907572; called by muse, mutect2, varscan2
- PCDHA1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 219/533 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.133); catalogued as rs782653718, COSV65372619; called by muse, mutect2, varscan2
- PCDHA5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 264/606 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as rs1181395519; called by muse, mutect2, varscan2
- PITPNM1 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs766703099; called by muse, mutect2, varscan2
- PLA2R1 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs142117970, COSV99321900; called by muse, mutect2, varscan2
- PSG4 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs540660899, COSV54939642; called by muse, mutect2, varscan2
- RSPO3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 135/359 reads (38%) | catalogued as rs773759447, COSV63150663; called by muse, mutect2, varscan2
- SAMD3 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs754761639; called by muse, mutect2, varscan2
- SCN11A | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs759694252, COSV56565060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3B3 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs765817626; called by muse, mutect2
- SPAM1 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV56147979; called by muse, mutect2
- ST18 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1182804514, COSV52495892; called by muse, mutect2, varscan2
- TAF7 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 123/327 reads (38%) | catalogued as COSV57664829; called by muse, mutect2, varscan2
- TLR8 | c.1909G>A p.G637S (on ENST00000218032 / NM_138636.5; = p.G655S on NM_016610.4) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs779645774; called by muse, mutect2, varscan2
- TMEM132C | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as rs931422934, COSV100175191; called by muse, mutect2, varscan2
- TNS3 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs575738038, COSV60788562; called by muse, mutect2, varscan2
- TRHDE | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs367558141, COSV99672037; called by muse, mutect2, varscan2
- TSHZ2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs779892655, COSV61589413; called by muse, mutect2, varscan2
- UBE4A | c.631C>G p.R211G | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV52802689; called by muse, mutect2, varscan2
- UTP14A | c.173+5C>T | Splice Region (SNP) | VAF 40/86 reads (47%) | catalogued as rs773067456; called by muse, mutect2, varscan2
- VPS13C | c.1360C>T p.R454W (on ENST00000644861 / NM_020821.3; = p.R411W on NM_017684.5) | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs370789719, COSV51196621; called by muse, mutect2, varscan2
- ZNF99 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764305477, COSV68055885; called by muse, varscan2
- ZP4 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs781226104, COSV63911494, COSV63913556; called by muse, mutect2, varscan2
- ACOX1 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACTR8 | c.1838T>C p.V613A | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2
- AHDC1 | c.2432C>A p.S811* | Nonsense Mutation (SNP) | VAF 93/210 reads (44%) | called by muse, mutect2, varscan2
- AHNAK2 | c.15982_15992del p.T5328Qfs*5 | Frame Shift Del (DEL) | VAF 63/184 reads (34%) | called by mutect2, pindel, varscan2
- CHRNB4 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CT47B1 | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 275/599 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ERBB2 | c.2008G>T p.V670F | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FRG1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GATA1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 217/556 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HS3ST4 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); called by muse, mutect2
- IGLV1-44 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); called by muse, mutect2
- IL22RA2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMC1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LIPT1 | c.428del p.Q143Rfs*51 | Frame Shift Del (DEL) | VAF 60/187 reads (32%) | called by mutect2, pindel, varscan2
- MDH1 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MSTO1 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NEFH | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PLCD1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 149/380 reads (39%) | called by muse, mutect2, varscan2
- PLG | c.991dup p.R331Kfs*18 | Frame Shift Ins (INS) | VAF 106/192 reads (55%) | called by mutect2, pindel, varscan2
- PTN | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 156/560 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PTPRC | c.2094G>C p.E698D | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ST18 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 175/430 reads (41%) | called by muse, mutect2, varscan2
- UPF3B | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- WIZ | c.5314+2T>G p.X1772_splice (on ENST00000673675 / NM_001371589.1; = p.X677_splice on NM_021241.3) | Splice Site (SNP) | VAF 86/285 reads (30%) | called by muse, mutect2, varscan2
- ZP4 | c.1377T>A p.C459* | Nonsense Mutation (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- ACP3 | c.801C>A p.I267= | Silent (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- BPI | c.1323C>T p.P441= (on ENST00000262865; = p.P437= on NM_001725.3) | Silent (SNP) | VAF 79/181 reads (44%) | called by muse, mutect2, varscan2
- CATSPERD | c.1530C>T p.C510= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs1404810511, COSV58466385; called by muse, mutect2, varscan2
- CTPS2 | c.1497T>C p.F499= | Silent (SNP) | VAF 65/197 reads (33%) | called by muse, mutect2, varscan2
- CUBN | c.10728C>T p.N3576= | Silent (SNP) | VAF 206/284 reads (73%) | catalogued as rs368511477; called by muse, mutect2, varscan2
- DDX4 | c.2070C>T p.N690= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as rs375133678; called by muse, mutect2, varscan2
- DRD2 | c.114C>T p.A38= | Silent (SNP) | VAF 203/521 reads (39%) | catalogued as rs754859319; called by muse, mutect2, varscan2
- FADS6 | c.888C>T p.F296= | Silent (SNP) | VAF 129/346 reads (37%) | catalogued as rs756928216; called by muse, mutect2, varscan2
- FSTL5 | c.1032G>T p.R344= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- GJA4 | c.759C>A p.G253= | Silent (SNP) | VAF 122/306 reads (40%) | catalogued as rs761671418; called by muse, mutect2, varscan2
- GPR173 | c.705C>T p.P235= | Silent (SNP) | VAF 171/349 reads (49%) | catalogued as rs781789348, COSV60234922; called by muse, mutect2, varscan2
- IL1RL2 | c.228C>T p.D76= | Silent (SNP) | VAF 108/246 reads (44%) | catalogued as rs769263185, COSV51817055; called by muse, mutect2, varscan2
- JPH3 | c.870C>T p.G290= | Silent (SNP) | VAF 154/412 reads (37%) | catalogued as rs144950183; called by muse, mutect2, varscan2
- JSRP1 | c.648C>T p.G216= | Silent (SNP) | VAF 256/940 reads (27%) | catalogued as rs775356580; called by muse, mutect2, varscan2
- KIAA1522 | c.834C>T p.P278= (on ENST00000373480 / NM_001198972.2; = p.P337= on NM_020888.3) | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs1557434758; called by muse, mutect2, varscan2
- LRRC66 | c.1683G>A p.T561= | Silent (SNP) | VAF 111/336 reads (33%) | catalogued as rs1485142183; called by muse, mutect2, varscan2
- MLN | c.69G>A p.T23= | Silent (SNP) | VAF 69/210 reads (33%) | catalogued as rs200908170; called by muse, mutect2, varscan2
- MTHFD2L | c.873C>T p.N291= (on ENST00000395759 / NM_001144978.2; = p.N233= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- NOTO | c.183C>T p.C61= | Silent (SNP) | VAF 146/336 reads (43%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2841G>A p.A947= | Silent (SNP) | VAF 75/399 reads (19%) | catalogued as rs371349360, COSV63754489; called by muse, mutect2, varscan2
- POM121C | c.1314T>C p.C438= (on ENST00000607367; = p.C196= on NM_001099415.3) | Silent (SNP) | VAF 58/253 reads (23%) | called by muse, mutect2, varscan2
- RIMS1 | c.186G>A p.A62= | Silent (SNP) | VAF 163/370 reads (44%) | catalogued as rs773456988, COSV53453239; called by muse, mutect2, varscan2
- RIPPLY3 | c.243C>T p.V81= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV61566779; called by muse, varscan2
- SEC14L1 | c.1533G>A p.E511= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as rs777954988, COSV101171182; called by muse, mutect2, varscan2
- SGCD | c.267C>T p.Y89= (on ENST00000435422 / NM_001128209.2; = p.Y90= on NM_000337.5) | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs749273088, COSV61903556; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SHKBP1 | c.393G>A p.P131= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as rs369135514; called by muse, mutect2, varscan2
- SLC22A6 | c.663C>T p.C221= | Silent (SNP) | VAF 153/359 reads (43%) | catalogued as rs768657635, COSV64560871; called by muse, mutect2, varscan2
- SPATA31A3 | c.2784G>A p.T928= | Silent (SNP) | VAF 80/213 reads (38%) | catalogued as rs917901920; called by mutect2, varscan2
- TDRD9 | c.585C>T p.I195= | Silent (SNP) | VAF 201/448 reads (45%) | catalogued as rs568864077; called by muse, mutect2, varscan2
- TMEM132D | c.582C>T p.A194= | Silent (SNP) | VAF 144/367 reads (39%) | catalogued as rs774769439, COSV70601732, COSV70611655; called by muse, mutect2, varscan2
- USP7 | c.3015C>A p.I1005= | Silent (SNP) | VAF 99/243 reads (41%) | called by muse, mutect2, varscan2
- ZC3H4 | c.1197C>T p.F399= | Silent (SNP) | VAF 43/347 reads (12%) | catalogued as rs1045488499, COSV53414427; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9100C>T | Intron (SNP) | VAF 91/866 reads (11%) | called by muse, mutect2, varscan2
- AOC4P | n.1551G>A | RNA (SNP) | VAF 75/172 reads (44%) | catalogued as rs547670131; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501251 del AT | 5'Flank (DEL) | VAF 23/88 reads (26%) | catalogued as rs751290649; called by pindel, varscan2
- AP1S3 | c.*38_*43del | 3'UTR (DEL) | VAF 3/25 reads (12%) | catalogued as rs1559269620; called by pindel, varscan2*
- BRWD3 | c.2231+18C>T | Intron (SNP) | VAF 26/195 reads (13%) | catalogued as rs780387370; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37164282 C>T | 3'Flank (SNP) | VAF 35/107 reads (33%) | catalogued as rs749261159, COSV57057972; called by muse, mutect2, varscan2
- CREB3L3 | c.-37C>T | 5'UTR (SNP) | VAF 36/365 reads (10%) | catalogued as rs766264988; called by muse, mutect2
- EYS | c.1767-8201G>A | Intron (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- FOXI2 | chr10:127736626 C>T | 5'Flank (SNP) | VAF 23/28 reads (82%) | called by muse, mutect2, varscan2
- HDAC4 | c.*19G>A | 3'UTR (SNP) | VAF 76/224 reads (34%) | catalogued as rs369993665; called by muse, mutect2, varscan2
- IL17RE | c.802+18G>A | Intron (SNP) | VAF 25/181 reads (14%) | catalogued as rs375206855; called by muse, mutect2, varscan2
- MIR517B | n.45C>T | RNA (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- PLEKHG6 | c.1524+539G>A | Intron (SNP) | VAF 34/170 reads (20%) | catalogued as rs951676751; called by muse, mutect2, varscan2
- RAPGEF5 | c.871-41G>A | Intron (SNP) | VAF 28/130 reads (22%) | catalogued as rs1014590594; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451362 C>T | 5'Flank (SNP) | VAF 106/413 reads (26%) | catalogued as COSV99989789; called by muse, mutect2, varscan2
